Somatic mutation profile of tumor specimen TCGA-97-A4M1-01A (aliquot TCGA-97-A4M1-01A-11D-A24P-08) from TCGA case TCGA-97-A4M1, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 52.8 years (19,272 days).
Specimen TCGA-97-A4M1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e80d102-460c-4555-a5b0-8c95a1676712.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-97-A4M1-10A (Blood Derived Normal), aliquot TCGA-97-A4M1-10A-01D-A24P-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4156a36-d1e3-4de0-9427-0effe07cbe21

The open-access MAF lists 45 somatic variants for this specimen: 35 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 32, Silent 10, Frame Shift Del 1, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 17/141 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- SEC24D | c.1450C>T p.R484* | Nonsense Mutation (SNP) | VAF 8/74 reads (11%) | catalogued as rs1372766642, COSV99756629, COSV99756660; ClinVar: pathogenic; called by muse, mutect2
- A1CF | c.332A>C p.N111T | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as COSV99257364; called by muse, mutect2, varscan2
- ADAM30 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.105); catalogued as COSV101023953, COSV101023999; called by muse, mutect2
- ANO3 | c.2242C>T p.L748F | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.166); catalogued as COSV99884937, COSV99885378; called by muse, mutect2, varscan2
- CHRDL1 | c.1114G>A p.V372I (on ENST00000372045; = p.V378I on NM_145234.4) | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.959); catalogued as rs747422590, COSV54323200; called by muse, mutect2, varscan2
- CPT1B | c.341C>T p.T114M | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs750519832, COSV56415446; called by muse, mutect2, varscan2
- CSPP1 | c.2749C>T p.H917Y (on ENST00000676605; = p.H876Y on NM_024790.6) | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.452); catalogued as COSV99139521; called by muse, mutect2
- DIAPH3 | c.1511A>G p.E504G (on ENST00000400324 / NM_001042517.2; = p.E241G on NM_030932.3) | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs956424200, COSV99934211; called by muse, mutect2, varscan2
- FASTKD3 | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 12/225 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV99241987; called by muse, mutect2
- FOXA3 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV100141484; called by muse, mutect2
- FTCD | c.676C>G p.L226V | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.07); catalogued as COSV52429354, COSV99384599; called by muse, mutect2, varscan2
- LRP2 | c.12502G>A p.V4168M | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99789825; called by muse, mutect2
- MICAL3 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs868594284, COSV99262641; called by muse, mutect2
- MOB1B | c.535C>G p.L179V | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.964); catalogued as COSV58673643; called by muse, mutect2, varscan2
- MUC4 | c.13903G>A p.V4635M (on ENST00000463781 / NM_018406.7; = p.V399M on NM_004532.6) | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.272); catalogued as rs111517228; called by muse, mutect2, varscan2
- OAS2 | c.1988G>T p.W663L | Missense Mutation (SNP) | VAF 46/273 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100660283; called by muse, mutect2, varscan2
- OR4D1 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as rs758816903, COSV52125505; called by muse, mutect2, varscan2
- PDE2A | c.2434C>A p.Q812K | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV57802766; called by muse, mutect2, varscan2
- POU4F2 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs544750597, COSV55584502; called by muse, mutect2, varscan2
- RAPGEF4 | c.2962C>T p.R988W | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs779338366, COSV51394507; called by muse, mutect2, varscan2
- RYR2 | c.7590A>T p.R2530S | Missense Mutation (SNP) | VAF 19/205 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.114); catalogued as COSV100772221; called by muse, mutect2
- SERPINA6 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201880274, CM150499; called by muse, mutect2
- SLC39A2 | c.628G>T p.V210L | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.193); catalogued as COSV100068676; called by muse, mutect2
- ST6GALNAC1 | c.1665T>G p.D555E | Missense Mutation (SNP) | VAF 11/54 reads (20%) | PolyPhen possibly damaging (0.821); catalogued as COSV99336604; called by muse, mutect2, varscan2
- TNR | c.688T>A p.C230S | Missense Mutation (SNP) | VAF 15/212 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99690996; called by muse, mutect2
- TTN | c.58388G>A p.R19463K (on ENST00000591111; = p.R12039K on NM_003319.4) | Missense Mutation (SNP) | VAF 11/69 reads (16%) | PolyPhen probably damaging (0.987); catalogued as COSV59894093; called by muse, mutect2, varscan2
- USP32 | c.3679C>G p.R1227G | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100342654; called by muse, mutect2, varscan2
- WDR49 | c.785G>C p.R262P (on ENST00000308378 / NM_001366158.1; = p.R603P on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.46); catalogued as COSV100392863, COSV57718577; called by mutect2, varscan2
- WNK3 | c.2215G>C p.E739Q | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV63613208; called by muse, mutect2, varscan2
- XIRP2 | c.4405T>A p.S1469T (on ENST00000628543; = p.S1644T on NM_152381.6) | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.432); catalogued as COSV99746301; called by muse, mutect2, varscan2
- ZDBF2 | c.1865C>T p.A622V | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.056); catalogued as rs756082291, COSV100985367; called by muse, mutect2, varscan2
- CROCC | c.215A>G p.E72G | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.784); called by muse, mutect2
- LEPR | c.1640_1665del p.I547Nfs*12 | Frame Shift Del (DEL) | VAF 8/72 reads (11%) | called by mutect2, pindel
- TP53 | c.464_467delinsA p.T155_R156delinsN | In Frame Del (DEL) | VAF 20/54 reads (37%) | called by pindel, varscan2*
- CHL1 | c.3495C>G p.V1165= (on ENST00000397491 / NM_001253387.1; = p.V1181= on NM_006614.4) | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as COSV99852034; called by muse, mutect2, varscan2
- HSPG2 | c.3198G>T p.R1066= | Silent (SNP) | VAF 16/153 reads (10%) | catalogued as COSV101021052; called by muse, mutect2, varscan2
- KDM6A | c.1776G>A p.L592= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV100938513; called by muse, mutect2
- MTRR | c.1752A>G p.Q584= (on ENST00000264668; = p.Q557= on NM_002454.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 19/189 reads (10%) | catalogued as rs1053675446, COSV99241988; called by muse, mutect2, varscan2
- PIAS4 | c.333C>T p.L111= | Silent (SNP) | VAF 13/125 reads (10%) | catalogued as COSV53678652; called by muse, mutect2, varscan2
- PPP2R2C | c.999C>T p.Y333= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs747462237, COSV59445832; called by muse, mutect2, varscan2
- SLC10A1 | c.897C>A p.L299= | Silent (SNP) | VAF 21/137 reads (15%) | catalogued as COSV99384472; called by muse, mutect2, varscan2
- TAOK2 | c.2805G>C p.L935= | Silent (SNP) | VAF 26/312 reads (8%) | catalogued as COSV99665250; called by muse, mutect2
- TBC1D4 | c.3648C>G p.L1216= | Silent (SNP) | VAF 5/86 reads (6%) | catalogued as COSV100884754, COSV66487623; called by muse, mutect2
- TFAP4 | c.843C>A p.G281= | Silent (SNP) | VAF 5/61 reads (8%) | catalogued as COSV52598611, COSV99200090; called by muse, mutect2
